Surgical pathology report (de-identified scan), TCGA case TCGA-B5-A1MW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Duke, specimen TCGA-B5-A1MW-01A (Primary Tumor).

[page 1 of 3]
ICB-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium c54.1

2/24/11

Surg Path

CLINICAL HISTORY:

Malignant neoplasm corpus uteri, 182.0.

GROSS EXAMINATION:

A. "Uterus, cervix, tubes and ovaries (AF1)" --received fresh for frozen section and placed in formalin at is a 92 gram, 6.2 x 3.5 x 3.5 cm uterus with a 2.5 cm diameter cervix with 0.8 cm diameter patent os. Attached to the uterus is a 6 x 1 cm grossly unremarkable right fallopian tube and 4.5 x 1.2 x 1.2 cm grossly unremarkable right ovary. Also attached is a 6.5 x 1 cm grossly unremarkable left fallopian tube, and 4.6 x 1.5 x 1.2 cm grossly unremarkable left ovary. The cervix is grossly unremarkable. The serosal surface of the uterus is smooth, glistening, and grossly unremarkable.

The 3.7 x 2.7 cm endometrial cavity is entirely filled by an exophytic, friable mass. The mass appears to grossly involve the anterior and posterior lower uterine segments. It comes within 3 cm of the distal cervix. The exophytic mass is 1.5 cm deep and appears to grossly invade approximately 0.4 cm into a 1.3 cm thick myometrium. There are no other lesions noted in the myometrium or remainder of the specimen.

BLOCK SUMMARY:

- A1- representative section of right ovary
- A2- representative section of right fallopian tube
- A3- representative section of left ovary
- A4- representative section of left fallopian tube
- A5- representative section of anterior cervix
- A6- anterior lower uterine segment with respect to mass
- A7- posterior cervix
- A8- mass with respect to posterior lower uterine segment
- A9-13- representative sections of mass
- A14- frozen section remnant with deepest invasion, AF1

Reviewed by (initials)	2/24/11	

B. "Left external lymph node", received fresh and placed in formalin at is a 3 x 2 x 1 cm aggregate of fibroadipose tissue dissected for candidate lymph nodes.

BLOCK SUMMARY:

- B1- largest candidate lymph node, 1.8 cm in greatest dimension
- B2- two candidate lymph nodes, 0.8 cm in greatest dimension
- B3- remaining fibroadipose tissue

C. "Left obturator node", received fresh and placed in formalin at is a 5 x 2.5 x 1.5 cm aggregate of fibroadipose tissue dissected for candidate lymph nodes.

BLOCK SUMMARY:

- C1- largest candidate lymph node, 1.4 cm in greatest dimension, bisected
- C2- two candidate lymph nodes, 1.5 cm in greatest dimension
- C3- three candidate lymph nodes, 1.2 cm in greatest dimension
- C4- three candidate lymph nodes, 0.8 cm in greatest dimension
- C5- remaining fibroadipose tissue

D. "Right pelvic node", received fresh and placed in formalin at is a 5 x 3 x 1.8 cm aggregate of fibroadipose tissue dissected for

[page 2 of 3]
candidate lymph nodes.

BLOCK SUMMARY:

- D1- two candidate lymph nodes, 1.2 cm in greatest dimension
- D2- four candidate lymph nodes, 0.8 cm in greatest dimension
- D3- three candidate lymph nodes, 1 cm in greatest dimension
- D4- six candidate lymph nodes, 0.5 cm in greatest dimension
- D5- remaining fibroadipose tissue

E. "Left aortic node", received fresh and placed in formalin at _____ on _____
is a 1.5 x 1 x 0.8 cm aggregate of fibroadipose tissue dissected for
candidate lymph nodes.

BLOCK SUMMARY:

- E1- three candidate lymph nodes, 0.5 cm in greatest dimension
- E2- remaining fibroadipose tissue

F. "High left aortic node", received fresh and placed in formalin at _____ pm
on _____ is a 1.5 x 1 x 0.6 cm candidate lymph node, bisected, and submitted
in block F1.

G. "Right aortic lymph node", received fresh and placed in formalin at _____ pm
on _____ is a 2.5 x 1.5 x 1 cm aggregate of fibroadipose tissue dissected
for candidate lymph nodes.

BLOCK SUMMARY:

- G1- 3 x 0.8 x 0.6 cm lymph node, bisected
- G2- two candidate lymph nodes, 0.6 cm in greatest dimension
- G3- remaining fibroadipose tissue

Dr. _____ /Dr. _____ :/slides to Dr. _____ ,

INTRA OPERATIVE CONSULTATION:

A. "Uterus, cervix, tubes, and ovary": AF1- (representative mass)- high-grade
malignancy. The tumor invades less
than half of the myometrial thickness
(one section examined) (Dr. _____).

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Hysterectomy, bilateral salpingo-oophorectomy, lymph node sampling
PATHOLOGIC STAGE (AJCC 7th Edition): pT1a pN0 pMX

NOTE: Information on pathology stage and the operative procedure is
transmitted to this Institution's Cancer Registry as required for
accreditation by the Commission on Cancer. Pathology stage is based solely
upon the current tissue specimen being evaluated, and does not incorporate
information on any specimens submitted separately to our Cytology section,
past pathology information, imaging studies, or clinical or operative
findings. Pathology stage is only a component to be considered in determining
the clinical stage, and should not be confused with nor substituted for it.
The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. UTERUS, CERVIX, TUBES AND OVARIES (HYSTERECTOMY AND BILATERAL
SALPINGO-OOPHORECTOMY):

UTERUS: 92 GRAMS

CARCINOMA OF THE ENDOMETRIUM:

TUMOR SITE: DIFFUSE.

HISTOLOGIC TYPE: ENDOMETRIOID ADENOCARCINOMA.

FIGO GRADE: 3.

[page 3 of 3]
TUMOR SIZE: 3.7 X 2.7 X 1.5 CM.
MAXIMUM DEPTH OF MYOMETRIAL INVASION: 0.4 CM, IN A 1.3 THICK WALL.
LYMPHATIC/VASCULAR INVASION: ABSENT.
ADJACENT NON-NEOPLASTIC ENDOMETRIUM: ABSENT.
REMAINING MYOMETRIUM: ADENOMYOSIS.
CERVIX: FREE OF TUMOR.
SEROSEA: FREE OF TUMOR.
SPECIMEN MARGINS: NOT INVOLVED.

OVARIES, RIGHT AND LEFT: FREE OF TUMOR.
FALLOPIAN TUBE, RIGHT AND LEFT: FREE OF TUMOR.

B. LEFT EXTERNAL LYMPH NODE (LYMPH NODE DISSECTION):

TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

C. LEFT OBTURATOR NODE (LYMPH NODE DISSECTION):

ELEVEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/11).

D. RIGHT PELVIC NODE (LYMPH NODE DISSECTION):

EIGHTEEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/18).

E. LEFT AORTIC NODE (LYMPH NODE DISSECTION):

THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

F. HIGH LEFT AORTIC NODE (BIOPSY):

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

G. RIGHT AORTIC LYMPH NODE (LYMPH NODE DISSECTION):

FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/4).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

CI ADDENDUM 1:

Please see Image Cytometry Report

for results of supplementary

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

Performed by:

[REDACTED]

Ordering MD:

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 6eb908db-26d0-4141-aa48-3bd77bc7b2e8 (TCGA-B5-A1MW.870882D8-D89A-4A89-B516-DADAB95BE285.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).